Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A735, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A735-01A (Primary Tumor).

ICD-O-3
Astrocytoma, grade II 9400/3
Site: Brain, supratentorial NOS
C71.0
JW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by white -gray pieces of right left temporal lobe

Microscopic description:

Received material consists with diffuse astrocytoma with moderate nuclear polymorphism. Ki-67 focally up to 7%

Final diagnosis: Diffuse astrocytoma; Grade II

Confidential

Source: NCI Genomic Data Commons file 191c5c43-b7f4-4b16-9710-024180600d88 (TCGA-P5-A735.7950CF04-F8C0-4855-A108-BB15B1B65B0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).